FM case AD11446 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/f69079a7-d843-44e8-9251-918b194c6d5e

Male, 64.5 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the major salivary gland. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
